MMRF case MMRF_1610 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c0e899b6-8479-406e-aa39-1db7281992ee

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.0 years (19,357 days); ISS stage: I; Days to last known disease status: 1,234 days (3.4 years); Days to last follow up: 1,234 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 150 days; Days to treatment end: 152 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 153 days; Days to treatment end: 153 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.41 mg/dL; Immunoglobulin G 36.6 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.58 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 4.9 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 9.4 g/dL; Glucose 5.4 mmol/L.
- Day 102 (ECOG 1): M Protein 9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Beta 2 Microglobulin 2.24 µg/mL; Hemoglobin 9.42 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 70 µmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 8 g/dL; Glucose 5.2 mmol/L.
- Day 172 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 43 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.05 mmol/L; Albumin 29 g/L; Total Protein 5.6 g/dL; Glucose 5.8 mmol/L.
- Day 255 (ECOG 0): M Protein 7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 60 µmol/L; Blood Urea Nitrogen 5.1 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6.5 mmol/L.
- Day 367 (ECOG 0): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 5.7 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.9 mmol/L.
- Day 452 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.7 mmol/L; Calcium 2.24 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 5.9 mmol/L.
- Day 536 (ECOG 0): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.79 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 73 µmol/L; Blood Urea Nitrogen 4 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.8 mmol/L.
- Day 619: M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL.
- Day 703 (ECOG 0): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 73 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 5.5 mmol/L.
- Day 821 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.2 mmol/L; Calcium 2.19 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 5.1 mmol/L.
- Day 904 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Immunoglobulin G 17.8 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 73 µmol/L; Blood Urea Nitrogen 5.1 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 6.8 mmol/L.
- Day 1,010 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 6.1 mmol/L.
- Day 1,173 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 4.7 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 5.9 mmol/L.
- Day 1,234 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 72 µmol/L; Blood Urea Nitrogen 4.8 mmol/L; Calcium 2.22 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day -5: Weight: 101 kg; Height: 184 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1610_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1610_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
